Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7325, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7325-01B (Primary Tumor).

Collection Date: [REDACTED]

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT AND LEFT PELVIC, EXCISION – NO EVIDENCE OF NEOPLASIA IN 9 LYMPH NODES (0/9).

PART 2: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 3+4=7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.0 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. CARCINOMA INVOLVES BILATERAL SEMINAL VESICLES.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3b N0 MX.
- K. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	42.3gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	9
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file ffdac1ce-e4b7-4522-bf6d-99f05d56c171 (TCGA-EJ-7325.6E9EC98C-FD89-47DA-BF8A-B7F4229C9E09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).